Somatic mutation profile of tumor specimen TCGA-EJ-5511-01A (aliquot TCGA-EJ-5511-01A-01D-1576-08) from TCGA case TCGA-EJ-5511, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.9 years (20,409 days).
Specimen TCGA-EJ-5511-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adb33d63-b170-4394-b599-3d65071e78bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5511-10A (Blood Derived Normal), aliquot TCGA-EJ-5511-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbf7c151-23bf-49ea-9ff8-41899818388f

The open-access MAF lists 38 somatic variants for this specimen: 26 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 11, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP9 | c.8393T>G p.L2798R (on ENST00000359028; = p.L2774R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.569); catalogued as COSV62359541; called by muse, mutect2, varscan2
- ATM | c.6490G>A p.E2164K | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1317619286, COSV53730905, COSV53774759; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST8 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs777164663, COSV52858558; called by muse, mutect2, varscan2
- CSMD1 | c.1918G>A p.A640T (on ENST00000520002; = p.A639T on NM_033225.6) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.998); catalogued as rs779494957, COSV59292435; called by muse, mutect2, varscan2
- CXorf58 | c.337T>C p.F113L | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0.05); PolyPhen benign (0.406); catalogued as COSV64858927; called by muse, mutect2, varscan2
- FST | c.638C>A p.T213N | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs767672190, COSV56817146; called by muse, mutect2, varscan2
- FZD2 | c.1005C>G p.Y335* | Nonsense Mutation (SNP) | VAF 36/108 reads (33%) | catalogued as COSV59530540; called by muse, varscan2
- FZD2 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59530550; called by muse, varscan2
- GBP1 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.26); catalogued as COSV65084702; called by muse, mutect2
- GFPT2 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs552846107, COSV53813334; called by muse, mutect2
- GIMAP7 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs761959705, COSV57958744, COSV57960327; called by muse, mutect2, varscan2
- GRB7 | c.228T>G p.S76R | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV58451465; called by muse, mutect2
- GRIA4 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs189218754; called by mutect2, varscan2
- HCN4 | c.2284G>T p.A762S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99983670; called by muse, mutect2, varscan2
- HFM1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs146051438; called by muse, mutect2, varscan2
- KANSL1L | c.1428+2T>G p.X476_splice | Splice Site (SNP) | VAF 7/88 reads (8%) | catalogued as COSV55998069; called by muse, mutect2
- KCND3 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.224); catalogued as rs751093070, COSV56189680; called by muse, mutect2, varscan2
- KCNH1 | c.1662G>T p.K554N (on ENST00000271751 / NM_172362.3; = p.K527N on NM_002238.4) | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV55087445; called by muse, mutect2, varscan2
- KLHL13 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV53254053; called by muse, mutect2
- LRP12 | c.1169C>A p.T390N | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV52635588; called by muse, mutect2, varscan2
- PCDH17 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64980502; called by muse, mutect2, varscan2
- ROR2 | c.1934A>G p.Y645C | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65224289; called by muse, mutect2, varscan2
- SHPRH | c.3676G>C p.A1226P (on ENST00000275233 / NM_001042683.3; = p.A1230P on NM_173082.3) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV51619321; called by muse, mutect2, varscan2
- SLC25A20 | c.739A>C p.N247H | Missense Mutation (SNP) | VAF 88/224 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV59805059; called by muse, mutect2, varscan2
- ARID4B | c.2917_2944del p.A973* | Frame Shift Del (DEL) | VAF 61/262 reads (23%) | called by mutect2, pindel
- TTN | c.80886dup p.P26963Tfs*4 (on ENST00000591111; = p.P19539Tfs*4 on NM_003319.4) | Frame Shift Ins (INS) | VAF 12/106 reads (11%) | called by mutect2, pindel, varscan2
- CCSER1 | c.228T>C p.S76= | Silent (SNP) | VAF 57/153 reads (37%) | catalogued as COSV61476333; called by muse, mutect2, varscan2
- ETV4 | c.285C>T p.I95= | Silent (SNP) | VAF 38/58 reads (66%) | catalogued as COSV60045726; called by muse, mutect2, varscan2
- FZD2 | c.423C>T p.F141= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as COSV59530520; called by muse, mutect2, varscan2
- FZD2 | c.1155C>T p.I385= | Silent (SNP) | VAF 64/180 reads (36%) | catalogued as COSV59530560; called by muse, varscan2
- FZD2 | c.1443C>T p.F481= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV59528590; called by muse, mutect2, varscan2
- IGSF9B | c.3036C>A p.I1012= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV58073938; called by muse, mutect2
- PTPN3 | c.1032G>A p.V344= | Silent (SNP) | VAF 82/209 reads (39%) | catalogued as COSV52711884; called by muse, mutect2, varscan2
- RAPGEF1 | c.1686G>A p.S562= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs937593427, COSV64702697; called by muse, mutect2, varscan2
- SGCD | c.660C>T p.C220= (on ENST00000435422 / NM_001128209.2; = p.C221= on NM_000337.5) | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV61918343; called by muse, mutect2, varscan2
- SYNE1 | c.363A>T p.I121= (on ENST00000367255 / NM_182961.4; = p.I128= on NM_033071.3) | Silent (SNP) | VAF 29/196 reads (15%) | catalogued as COSV55126664; called by muse, mutect2, varscan2
- ZNF592 | c.231G>A p.E77= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as COSV55440230; called by muse, mutect2
- AC024940.1 | n.2882T>C | RNA (SNP) | VAF 12/362 reads (3%) | called by muse, mutect2
